Somatic mutation profile of tumor specimen TARGET-20-PATDRL-09A (aliquot TARGET-20-PATDRL-09A-01D) from TARGET case TARGET-20-PATDRL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,657 days).
Specimen TARGET-20-PATDRL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12fd28b9-f980-452d-9fe1-121d73b17164.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDRL-14A (Bone Marrow Normal), aliquot TARGET-20-PATDRL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db6afc8f-1e9b-4bf6-a442-afffa8332e86

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCBP2 | c.11941A>G p.M3981V (on ENST00000357337; = p.M4019V on NM_015057.5) | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV62010170; called by muse, mutect2, varscan2
- EZH2 | c.1906G>T p.E636* (on ENST00000460911 / NM_001203247.2; = p.E641* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- KRAS | c.76_77insGG p.N26Rfs*12 | Frame Shift Ins (INS) | VAF 17/99 reads (17%) | called by mutect2, pindel*, varscan2*
- PHF6 | c.498dup p.P167Afs*5 (on ENST00000332070 / NM_032458.3; = p.P168Afs*5 on NM_032335.3) | Frame Shift Ins (INS) | VAF 25/42 reads (60%) | called by mutect2, pindel, varscan2
- SLFN11 | c.2699G>T p.G900V | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
